Somatic mutation profile of tumor specimen TCGA-50-5941-01A (aliquot TCGA-50-5941-01A-11D-1753-08) from TCGA case TCGA-50-5941, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.7 years (20,350 days).
Specimen TCGA-50-5941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ab41759-32a6-4b72-911f-507260ed2c9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5941-10A (Blood Derived Normal), aliquot TCGA-50-5941-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2c19b73-08e1-4dde-bfa3-a97313c2051c

The open-access MAF lists 398 somatic variants for this specimen: 306 protein-altering or splice-affecting, 83 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 83, Nonsense Mutation 20, Frame Shift Del 13, Splice Site 7, Intron 6, Frame Shift Ins 5, RNA 2, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTD | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | catalogued as rs397514338, CM051397, COSV57728979, COSV57730788; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.232-1G>T p.X78_splice | Splice Site (SNP) | VAF 16/67 reads (24%) | catalogued as rs104886350, CS010533, CS155145, COSV60373736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GDF5 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs397514668, CM081281, COSV65503860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 24/63 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 26/159 reads (16%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCG8 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV55394952, COSV55397448; called by muse, mutect2, varscan2
- ACTL7B | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV65928278; called by muse, mutect2, varscan2
- ADAM11 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52350287; called by muse, mutect2
- ADAM7 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 10/45 reads (22%) | catalogued as COSV51544546; called by muse, mutect2, varscan2
- ADAMTS19 | c.968A>T p.Y323F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.556); catalogued as COSV50807284; called by muse, mutect2
- ADAMTS20 | c.2836G>C p.D946H | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101166335, COSV67140803; called by muse, mutect2, varscan2
- ADCY1 | c.835A>T p.M279L | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV52043740; called by muse, mutect2
- AFF2 | c.565T>G p.S189A | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV60684009; called by muse, mutect2
- AFF2 | c.1642C>A p.Q548K | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV54010100; called by muse, mutect2
- AHNAK2 | c.9873G>T p.E3291D | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV60933175; called by muse, mutect2
- ALMS1 | c.8778A>T p.Q2926H | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52523608; called by muse, mutect2
- ANKFN1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59461538; called by muse, mutect2, varscan2
- APBB3 | c.49+1G>A p.X17_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100021168; called by muse, mutect2, varscan2
- APOB | c.6409C>G p.H2137D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV51955787; called by muse, mutect2, varscan2
- ARFGEF2 | c.1896T>A p.D632E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV64215680; called by muse, mutect2
- ARHGAP44 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52404035; called by mutect2, varscan2
- ARL14EP | c.283T>G p.L95V | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV56343785; called by muse, mutect2
- ASTN1 | c.2709A>T p.R903S | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV62508497; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1129A>G p.I377V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV52355598; called by muse, mutect2, varscan2
- BDP1 | c.3183G>T p.E1061D | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV62435460; called by muse, mutect2
- BPIFB6 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as rs976798815, COSV62755929, COSV62756899; called by muse, mutect2, varscan2
- BRD1 | c.3142G>T p.G1048W (on ENST00000216267 / NM_001349940.1; = p.G1179W on NM_001304808.3) | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV53462298; called by muse, mutect2, varscan2
- BTBD3 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54782142; called by muse, mutect2, varscan2
- BTRC | c.947T>C p.I316T (on ENST00000370187 / NM_033637.4; = p.I280T on NM_003939.5) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64581339; called by muse, mutect2
- C2orf66 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61099106; called by muse, mutect2
- C6 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.031); catalogued as COSV54720386; called by muse, mutect2, varscan2
- CACNA2D1 | c.1750G>C p.G584R (on ENST00000356253 / NM_001366867.1; = p.G565R on NM_000722.4) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62394698; called by muse, mutect2, varscan2
- CC2D1A | c.2634G>C p.Q878H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV54310122; called by muse, mutect2, varscan2
- CCDC141 | c.1990A>G p.S664G | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV99836230; called by muse, mutect2
- CCDC63 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57531653; called by muse, mutect2, varscan2
- CD109 | c.3739G>C p.A1247P | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54647024, COSV54658058; called by muse, mutect2, varscan2
- CD163 | c.2075C>A p.S692* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV63131535, COSV63134805; called by muse, mutect2, varscan2
- CD274 | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as COSV67502016; called by muse, mutect2, varscan2
- CD5L | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV63820985, COSV63823341; called by muse, mutect2, varscan2
- CDH2 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52298466; called by muse, mutect2, varscan2
- CDH9 | c.2342A>T p.Y781F | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as rs765236056, COSV50515375, COSV50523238; called by muse, mutect2, varscan2
- CDX4 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV65172029; called by muse, mutect2, varscan2
- CFAP58 | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.019); catalogued as COSV63836758; called by muse, mutect2, varscan2
- CFHR2 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66381212; called by muse, mutect2, varscan2
- CIT | c.1871A>T p.Y624F | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55885486; called by muse, mutect2, varscan2
- CNTN1 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751002; called by muse, mutect2
- COL11A1 | c.3002C>A p.A1001D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.134); catalogued as rs1378524449, COSV62200341; called by muse, mutect2, varscan2
- COL3A1 | c.3043A>T p.N1015Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV58597808; called by muse, mutect2
- COL4A5 | c.3247G>T p.G1083C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM052215, COSV60373749; called by muse, mutect2, varscan2
- COL6A3 | c.7860G>T p.M2620I | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.245); catalogued as COSV55082570, COSV55113274; called by muse, mutect2, varscan2
- CORIN | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56700834; called by muse, mutect2, varscan2
- CPS1 | c.1748del p.P583Qfs*2 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as COSV51806815; called by mutect2, pindel, varscan2
- CRTAP | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58015265; called by muse, mutect2
- CYFIP2 | c.3691C>T p.R1231W (on ENST00000616178 / NM_001291722.2; = p.R1206W on NM_014376.4) | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59042298; called by muse, mutect2
- DAAM1 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV62840209; called by muse, mutect2
- DGKI | c.2672G>T p.R891L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV55979685; called by muse, mutect2, varscan2
- DIS3L | c.1057G>C p.E353Q (on ENST00000319212 / NM_001143688.3; = p.E270Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV59914734; called by muse, mutect2, varscan2
- DIXDC1 | c.1362C>A p.H454Q (on ENST00000440460 / NM_001037954.4; = p.H243Q on NM_033425.4) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59463822; called by muse, mutect2, varscan2
- DMBT1 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57565880; called by muse, mutect2
- DMD | c.5323A>T p.K1775* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV63798366; called by muse, mutect2, varscan2
- DNAI2 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV56762980; called by muse, mutect2
- DOCK2 | c.3340A>C p.M1114L | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56992464; called by muse, mutect2, varscan2
- DPP3 | c.1909G>C p.G637R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64758234; called by muse, mutect2, varscan2
- DPYSL5 | c.192C>G p.D64E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56516974; called by muse, mutect2, varscan2
- DYNC1H1 | c.9682G>T p.E3228* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV64143699; called by muse, mutect2, varscan2
- EDN3 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV61110558; called by muse, mutect2
- EHHADH | c.1292C>G p.T431S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV51633963; called by muse, mutect2
- ENOX1 | c.589+1G>C p.X197_splice | Splice Site (SNP) | VAF 7/160 reads (4%) | catalogued as COSV54921211; called by muse, mutect2
- EPB41L3 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59445371; called by muse, mutect2, varscan2
- EPHB6 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758096886, COSV63892832, COSV63894038; called by muse, mutect2, varscan2
- F13A1 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs768408371, COSV53568965; called by muse, mutect2, varscan2
- FAM171A1 | c.636C>A p.S212R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs760257001, COSV65320709; called by muse, mutect2, varscan2
- FAM83B | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV60927633; called by muse, mutect2
- FASN | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs202024339, COSV60757320; called by muse, mutect2, varscan2
- FBLN1 | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53054804; called by muse, mutect2
- FBN2 | c.2707C>A p.Q903K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV99325311; called by muse, mutect2, varscan2
- FLG | c.11342C>A p.S3781Y | Missense Mutation (SNP) | VAF 144/596 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64251170; called by muse, mutect2, varscan2
- FLG2 | c.4770C>G p.H1590Q | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV66174199; called by muse, mutect2, varscan2
- FLNB | c.4651C>A p.L1551M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); catalogued as COSV55898495; called by muse, mutect2
- FMO1 | c.743del p.P248Qfs*5 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | catalogued as COSV100707961; called by mutect2, varscan2
- FNDC1 | c.1974C>A p.H658Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV51949031; called by muse, mutect2, varscan2
- FNDC11 | c.710C>A p.S237* | Nonsense Mutation (SNP) | VAF 48/200 reads (24%) | catalogued as COSV100918758, COSV64443329; called by muse, mutect2, varscan2
- FUT11 | c.1214A>T p.H405L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); catalogued as COSV100226556; called by muse, mutect2
- GABRG2 | c.1384G>T p.E462* (on ENST00000361925 / NM_001375343.1; = p.E422* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/133 reads (20%) | catalogued as COSV62717413, COSV62723138; called by muse, mutect2, varscan2
- GCNT2 | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV65458962; called by muse, mutect2, varscan2
- GJA8 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV99569130; called by muse, mutect2, varscan2
- GPR183 | c.705A>C p.K235N | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100854121; called by muse, mutect2
- GPR183 | c.704A>T p.K235I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100854123; called by muse, mutect2
- GPR6 | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.396); catalogued as COSV51573898; called by muse, mutect2, varscan2
- GREM2 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100547312; called by muse, mutect2, varscan2
- GRID2 | c.2466A>T p.K822N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56277809; called by muse, mutect2
- GTF2IRD1 | c.1421G>C p.G474A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV56092539; called by muse, mutect2
- HABP2 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV63635907, COSV63638247; called by muse, mutect2, varscan2
- HCK | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as COSV52947698; called by muse, mutect2, varscan2
- HECTD2 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV53225426; called by muse, mutect2, varscan2
- HERC2 | c.4862G>T p.W1621L | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.901); catalogued as COSV99871350; called by muse, mutect2
- HLA-DMB | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV101186815; called by muse, mutect2
- HMGCS2 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV65569574; called by muse, mutect2, varscan2
- HOXA2 | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56067975, COSV56068083; called by muse, mutect2, varscan2
- HSD3B7 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52681262, COSV52682402; called by muse, mutect2, varscan2
- HSPA2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99904715; called by muse, mutect2
- HSPH1 | c.2566G>T p.D856Y | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60714215; called by muse, mutect2, varscan2
- HTATSF1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV54481907; called by muse, mutect2, varscan2
- IGF1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61035137; called by muse, mutect2
- INTU | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV56542660; called by muse, mutect2, varscan2
- IRS4 | c.1794A>T p.K598N | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.748); catalogued as COSV64536329; called by muse, mutect2, varscan2
- ITGA8 | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as COSV65225664, COSV65237267; called by muse, mutect2
- ITPR2 | c.7975C>G p.L2659V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV67277181; called by muse, mutect2, varscan2
- ITSN1 | c.3662-2A>T p.X1221_splice | Splice Site (SNP) | VAF 19/86 reads (22%) | catalogued as COSV67157717; called by muse, mutect2, varscan2
- KANSL1L | c.2814T>A p.D938E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV55997900; called by muse, mutect2, varscan2
- KIF26B | c.3858C>A p.S1286R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63653723; called by muse, mutect2
- KIN | c.1017A>T p.P339= | Splice Region (SNP) | VAF 12/134 reads (9%) | catalogued as COSV65431638; called by muse, mutect2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2
- LAMC3 | c.2057C>G p.S686C | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV63095860; called by muse, mutect2, varscan2
- LMO7 | c.1116A>T p.K372N (on ENST00000357063; = p.K102N on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV58550946; called by muse, mutect2, varscan2
- LRP1B | c.2706A>T p.R902S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV63342050; called by muse, mutect2, varscan2
- LRRC43 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60293908; called by muse, mutect2, varscan2
- LRRC49 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1436723876, COSV53016373; called by muse, mutect2
- LTBP2 | c.5401C>A p.R1801S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.842); catalogued as COSV56213824, COSV56214964; called by muse, mutect2
- LY75 | c.158G>T p.W53L | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV55113877; called by muse, mutect2, varscan2
- MAGEA10 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV54886307; called by muse, mutect2
- MAGEC1 | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV53572643; called by muse, mutect2
- MAGEC3 | c.1625G>C p.G542A | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV68924436; called by muse, mutect2
- MAGI1 | c.4035G>C p.K1345N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58347809; called by muse, mutect2, varscan2
- MAP3K9 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67123125; called by muse, mutect2
- MAP4 | c.1957C>G p.P653A | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV53143554; called by muse, mutect2, varscan2
- MARK1 | c.228G>T p.L76F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65071952; called by muse, mutect2, varscan2
- MCUR1 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as rs764389378, COSV63958305; called by muse, mutect2, varscan2
- MED13L | c.5739T>A p.S1913R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56131790; called by muse, mutect2, varscan2
- MED13L | c.4781C>T p.P1594L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV56131800; called by muse, mutect2, varscan2
- MMP16 | c.1222G>C p.G408R | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV54192604; called by muse, mutect2
- MRC1 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1380265793; called by mutect2, varscan2
- MUCL3 | c.1444C>G p.Q482E (on ENST00000304311; = p.Q1358E on NM_080870.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV58519217; called by muse, mutect2, varscan2
- MYH6 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 28/563 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62455099, COSV62455164; called by muse, mutect2
- MYH7 | c.2419C>A p.R807S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV62524798; called by mutect2, varscan2
- MYH8 | c.105T>G p.D35E | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as rs1449149762, COSV67973748; called by muse, mutect2, varscan2
- MYPN | c.3230A>C p.Q1077P | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62740661; called by muse, mutect2
- NAV3 | c.2617G>T p.V873L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV57116206; called by muse, mutect2
- NAV3 | c.5071G>C p.A1691P | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57116252; called by muse, mutect2
- NFXL1 | c.1154G>T p.C385F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61201093; called by muse, mutect2
- NLGN4Y | c.1806G>T p.E602D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV100196414; called by muse, mutect2, varscan2
- NLRP14 | c.2157G>T p.Q719H | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55072907; called by muse, mutect2, varscan2
- NOBOX | c.958G>T p.G320W | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV56192504, COSV56198326, COSV56198634; called by muse, mutect2, varscan2
- NOS3 | c.1996G>T p.A666S | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.423); catalogued as COSV52496641; called by muse, mutect2, varscan2
- NOTCH4 | c.3826G>C p.E1276Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV66679149, COSV66683077; called by muse, mutect2
- NOTCH4 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66684416; called by muse, mutect2, varscan2
- NSUN6 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV66033785, COSV66035618; called by muse, mutect2
- NUDT15 | c.356-2A>T p.X119_splice | Splice Site (SNP) | VAF 4/68 reads (6%) | catalogued as COSV99320232; called by muse, mutect2
- NUDT8 | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV56876778; called by muse, mutect2, varscan2
- OAS1 | c.146G>C p.S49T | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99177073; called by muse, mutect2
- OBSCN | c.8898G>T p.E2966D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV52838605; called by muse, mutect2, varscan2
- OR13F1 | c.689C>A p.S230* | Nonsense Mutation (SNP) | VAF 42/193 reads (22%) | catalogued as COSV58252806; called by muse, mutect2, varscan2
- OR14J1 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV101012717; called by muse, mutect2, varscan2
- OR14K1 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs367970677, COSV99314974; called by muse, mutect2, varscan2
- OR1L8 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59185880, COSV59187568; called by muse, mutect2, varscan2
- OR2A7 | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV101512185; called by muse, mutect2
- OR2T6 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV63216317; called by muse, mutect2, varscan2
- OR2W3 | c.491T>A p.L164Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64458222; called by muse, mutect2, varscan2
- OR4C15 | c.601G>A p.A201T (on ENST00000314644; = p.A147T on NM_001001920.2) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as rs778665594, COSV58956168; called by muse, mutect2, varscan2
- OR4C16 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV58944638; called by muse, mutect2, varscan2
- OR4K5 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60004549, COSV60004807; called by muse, mutect2
- OR51F2 | c.819T>G p.F273L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.034); catalogued as COSV59066252; called by muse, mutect2, varscan2
- OR52B2 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.713); catalogued as COSV73209700; called by muse, mutect2, varscan2
- OR5I1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs767149458, COSV56885885; called by mutect2, varscan2
- OR5T3 | c.282G>T p.L94F | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57382907; called by muse, mutect2, varscan2
- OR6C6 | c.911A>G p.Q304R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100626408; called by muse, mutect2, varscan2
- OR7C2 | c.337T>A p.L113M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV50182355; called by muse, mutect2, varscan2
- OR8U1 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.308); catalogued as COSV100163777; called by muse, varscan2
- OR9G1 | c.226T>A p.Y76N | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV56454584; called by muse, varscan2
- OTUD5 | c.1366C>G p.R456G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV50233804, COSV50240660, COSV99331981; called by muse, mutect2
- PAPOLG | c.604+1G>T p.X202_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as COSV53186193; called by muse, mutect2, varscan2
- PCDH15 | c.5464C>G p.P1822A | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.033); catalogued as COSV57405720; called by muse, mutect2
- PCDH8 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58811643, COSV58815321; called by muse, mutect2
- PCDHA11 | c.1898C>A p.T633K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV56501502, COSV56551821; called by muse, mutect2, varscan2
- PCDHA4 | c.2286G>T p.E762D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as COSV63546772; called by muse, mutect2, varscan2
- PCDHB12 | c.1144G>T p.V382F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV53401677; called by muse, mutect2, varscan2
- PCSK5 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV65095722, COSV65097810; called by muse, mutect2, varscan2
- PDE3A | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 157/248 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV62984090; called by muse, mutect2, varscan2
- PDZRN3 | c.2630C>A p.A877D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55217411; called by muse, mutect2, varscan2
- PELI2 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV50717215; called by muse, mutect2
- PLD5 | c.701G>T p.G234V (on ENST00000442594; = p.G172V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV59171381; called by muse, varscan2
- PLD5 | c.620C>T p.T207M (on ENST00000442594; = p.T145M on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs773800524, COSV59134030; called by muse, varscan2
- PLD5 | c.600A>T p.K200N (on ENST00000442594; = p.K138N on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.236); catalogued as COSV59171409; called by muse, mutect2
- PLEKHB2 | c.656T>C p.F219S (on ENST00000409279; = p.F218S on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52178581; called by muse, mutect2, varscan2
- PLG | c.2164C>A p.P722T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57521891; called by muse, mutect2, varscan2
- PNLIPRP1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62613792; called by muse, mutect2
- POLM | c.1220G>T p.R407M | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV54244240; called by muse, mutect2, varscan2
- POLQ | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV51762912; called by muse, mutect2
- POM121L12 | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.006); catalogued as rs1250105851, COSV68692910, COSV68694611; called by muse, mutect2, varscan2
- PPARGC1A | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 71/395 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV53534340; called by muse, mutect2, varscan2
- PREX1 | c.2550C>A p.H850Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV64257536; called by muse, mutect2, varscan2
- PSG8 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 72/375 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV60614840, COSV60616491; called by muse, mutect2, varscan2
- PSMD13 | c.764G>T p.W255L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV61502110; called by muse, mutect2, varscan2
- PTHLH | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 25/239 reads (10%) | catalogued as COSV52367331, COSV52369774; called by muse, mutect2, varscan2
- PTPRZ1 | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as rs1385342393, COSV66446822; called by muse, mutect2, varscan2
- RAB3B | c.286A>T p.M96L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100862453; called by muse, mutect2, varscan2
- RAD54B | c.1720G>T p.G574W | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60255443; called by muse, mutect2, varscan2
- RANBP2 | c.3707G>T p.R1236L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51703241, COSV51709720; called by muse, mutect2
- RANBP2 | c.5545G>A p.A1849T | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV51709727, COSV99312900; called by muse, mutect2
- RASIP1 | c.2617T>G p.Y873D | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99710527; called by muse, mutect2, varscan2
- REL | c.1824G>C p.L608F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.462); catalogued as COSV54367825; called by muse, mutect2, varscan2
- RELN | c.7399C>A p.Q2467K | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV59037680; called by muse, mutect2, varscan2
- RNASE2 | c.84A>T p.K28N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV58941632; called by muse, mutect2
- RP1L1 | c.6105G>T p.Q2035H | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as COSV66761122; called by muse, mutect2
- RYR2 | c.730T>A p.C244S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.31); catalogued as COSV63718911; called by muse, mutect2, varscan2
- SAMD9L | c.3130C>A p.R1044S | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV59085939; called by muse, mutect2, varscan2
- SCN10A | c.5671G>A p.D1891N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV71862787; called by muse, mutect2, varscan2
- SCN11A | c.5344G>A p.G1782R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV56579589; called by muse, mutect2, varscan2
- SCN3A | c.5916T>G p.S1972R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV51826674; called by muse, mutect2, varscan2
- SERPINE1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1397842827, COSV56171861; called by muse, mutect2
- SETD2 | c.1712_1713insG p.N571Kfs*10 | Frame Shift Ins (INS) | VAF 18/158 reads (11%) | catalogued as COSV100338135; called by mutect2, pindel, varscan2
- SH3GL2 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66056171, COSV66056451; called by muse, mutect2, varscan2
- SLC15A1 | c.1272A>G p.T424= | Splice Region (SNP) | VAF 15/168 reads (9%) | catalogued as rs1232145872, COSV64734072; called by muse, mutect2
- SLC15A1 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64713106; called by muse, mutect2, varscan2
- SLC18A3 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60334556; called by muse, mutect2
- SLC26A7 | c.412T>C p.S138P | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52605928; called by muse, mutect2
- SLC28A2 | c.1714G>C p.A572P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV61665486; called by muse, mutect2, varscan2
- SLC35G5 | c.623T>A p.L208Q | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV55315650; called by muse, mutect2, varscan2
- SLC52A3 | c.739T>A p.C247S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV54079639; called by muse, mutect2, varscan2
- SLC8A1 | c.2768G>T p.G923V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV60498360; called by muse, mutect2, varscan2
- SLCO1C1 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV56881239; called by muse, mutect2
- SLITRK1 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100999991, COSV65677914; called by muse, mutect2
- SLITRK2 | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs781927291, COSV59428056, COSV59428576, COSV59429530; called by muse, mutect2
- SLITRK4 | c.380T>C p.F127S | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62025008; called by muse, mutect2
- SLITRK6 | c.2006C>G p.T669S | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV68391944; called by muse, mutect2, varscan2
- SMTN | c.1506T>A p.S502R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV60783705; called by muse, mutect2
- SORCS1 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV53910925; called by muse, mutect2
- SPAG9 | c.400A>T p.K134* | Nonsense Mutation (SNP) | VAF 34/187 reads (18%) | catalogued as COSV56245147; called by muse, mutect2, varscan2
- SPAM1 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV56146663, COSV56148523, COSV99773261; called by muse, mutect2, varscan2
- SPATA18 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs183444588; called by muse, mutect2, varscan2
- SPATA31D1 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as COSV61202159; called by muse, mutect2, varscan2
- SPTA1 | c.2722C>A p.L908M | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV63760800; called by muse, mutect2, varscan2
- SPTA1 | c.2450C>G p.T817S | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV63760807; called by muse, mutect2
- ST8SIA6 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV66472224; called by muse, mutect2
- STXBP5L | c.3358G>C p.G1120R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1350678711, COSV56538147; called by muse, mutect2
- SUSD1 | c.620G>C p.R207T | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs762573538, COSV62585680; called by muse, mutect2
- SYNDIG1 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV65238118; called by muse, mutect2, varscan2
- TAAR1 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV99257474; called by muse, mutect2, varscan2
- TBC1D16 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60478343; called by muse, mutect2, varscan2
- TBRG4 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV51834724; called by muse, mutect2
- TENM1 | c.5860G>T p.G1954C | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64445710; called by muse, mutect2
- TENM2 | c.3944C>A p.S1315Y (on ENST00000518659 / NM_001122679.2; = p.S1076Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.862); catalogued as COSV69143696; called by muse, mutect2, varscan2
- TGIF2LX | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV52215080, COSV52215374, COSV99383415; called by muse, mutect2
- TGM6 | c.1253A>G p.K418R | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV52484896; called by muse, mutect2, varscan2
- THSD7B | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55744895, COSV99745992; called by muse, mutect2, varscan2
- TLCD3B | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs779223633, COSV54228417; called by muse, mutect2, varscan2
- TMEM132E | c.1590G>A p.W530* (on ENST00000321639; = p.W620* on NM_001304438.2) | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV58701024; called by muse, mutect2
- TMEM156 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV60745883; called by muse, mutect2, varscan2
- TMPRSS11F | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62469913; called by muse, mutect2, varscan2
- TMTC1 | c.2224C>T p.H742Y (on ENST00000539277 / NM_001193451.2; = p.H634Y on NM_175861.3) | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.331); catalogued as COSV55495102; called by muse, varscan2
- TPO | c.2530C>A p.L844I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV61112560; called by muse, mutect2, varscan2
- TPR | c.6861G>C p.Q2287H | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV66605625; called by muse, mutect2, varscan2
- TRAV8-1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1167236070; called by muse, mutect2
- TRIM48 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70163465; called by muse, mutect2, varscan2
- TRPC7 | c.2454C>A p.S818R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61464976; called by muse, mutect2, varscan2
- TSC1 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100051241; called by mutect2, varscan2
- TSHZ3 | c.1263G>C p.K421N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53684766; called by muse, mutect2, varscan2
- TTN | c.9236G>T p.C3079F (on ENST00000591111; = p.C3033F on NM_003319.4) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | PolyPhen possibly damaging (0.837); catalogued as COSV60391520; called by muse, mutect2, varscan2
- TULP4 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV65581708; called by muse, mutect2, varscan2
- UBA6 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59181391; called by muse, mutect2
- UQCRFS1 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV59185539; called by muse, mutect2
- UST | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100819820, COSV66550894; called by muse, mutect2
- VANGL2 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 6/145 reads (4%) | catalogued as COSV63605595; called by muse, mutect2
- WDFY3 | c.925G>T p.G309* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV99882267; called by muse, mutect2, varscan2
- WSCD1 | c.1328G>C p.C443S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.945); catalogued as COSV58498922; called by muse, mutect2, varscan2
- WT1 | c.1313C>A p.P438Q | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV60085374; called by muse, mutect2, varscan2
- XIRP2 | c.3632C>G p.S1211C (on ENST00000628543; = p.S1386C on NM_152381.6) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54691796, COSV54738720, COSV99747449; called by muse, mutect2, varscan2
- XRN1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV53819116; called by muse, mutect2
- YLPM1 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV53122023; called by muse, mutect2, varscan2
- ZBTB20 | c.1604A>T p.Q535L (on ENST00000474710 / NM_001164342.2; = p.Q462L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); catalogued as COSV61872482; called by muse, mutect2, varscan2
- ZFHX4 | c.2433G>T p.L811F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV50696050; called by muse, mutect2, varscan2
- ZFP69 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV65529714; called by muse, mutect2, varscan2
- ZMYND8 | c.626G>T p.C209F (on ENST00000311275 / NM_001363741.2; = p.C229F on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV53697372; called by muse, mutect2, varscan2
- ZNF208 | c.2791G>C p.V931L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.044); catalogued as COSV68113555; called by muse, mutect2, varscan2
- ZNF257 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs555293490, COSV71310222, COSV71312175, COSV71312346; called by muse, mutect2, varscan2
- ZNF451 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100674683; called by muse, mutect2, varscan2
- ZNF521 | c.2822C>A p.S941Y | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64122720, COSV64132634; called by muse, mutect2, varscan2
- ZNF532 | c.3112G>C p.D1038H | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV60176217; called by muse, mutect2
- ZNF560 | c.2370C>A p.H790Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV56872236; called by muse, mutect2, varscan2
- ZNF585B | c.305G>C p.W102S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100459319, COSV100459321; called by muse, mutect2
- ZNF585B | c.304T>A p.W102R | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753069441, COSV100459320; called by muse, mutect2
- ZNF665 | c.1774A>T p.N592Y (on ENST00000600412; = p.N657Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV67218010; called by muse, mutect2
- ZNF695 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100377271, COSV60587727; called by muse, mutect2, varscan2
- ZNF768 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs779839168, COSV63324751; called by muse, mutect2
- ZNF831 | c.4645T>A p.S1549T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); catalogued as rs1248380657, COSV64045885; called by muse, mutect2, varscan2
- ZSWIM3 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54852111; called by muse, mutect2, varscan2
- CSAG3 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- CSRNP3 | c.1449del p.A484Qfs*17 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- DDX5 | c.470_473del p.N157Ifs*5 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by pindel, varscan2
- FGD4 | c.471del p.T158Lfs*4 | Frame Shift Del (DEL) | VAF 42/143 reads (29%) | called by mutect2, pindel, varscan2
- IGHV1OR15-9 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2
- KDM1B | c.2425del p.A809Hfs*3 (on ENST00000449850; = p.A576Hfs*3 on NM_153042.4) | Frame Shift Del (DEL) | VAF 25/225 reads (11%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.2261G>A p.S754N (on ENST00000619416 / NM_001244190.2; = p.S693N on NM_014749.5) | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0); called by mutect2, varscan2
- LRP1B | c.13332dup p.A4445Cfs*24 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- MAP3K12 | c.1467del p.I490Sfs*29 | Frame Shift Del (DEL) | VAF 20/166 reads (12%) | called by mutect2, pindel, varscan2
- MON2 | c.3724del p.A1242Lfs*23 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- MTMR9 | c.1649del p.*550= | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, varscan2
- NELL1 | c.2173dup p.C725Lfs*12 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- NSG1 | c.234del p.E79Rfs*69 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- PSG1 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- PXYLP1 | c.803dup p.N268Kfs*23 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, varscan2
- REG3A | c.272del p.L91Rfs*2 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- SAMD9 | c.3652_3653insC p.D1218Afs*2 | Frame Shift Ins (INS) | VAF 18/136 reads (13%) | called by mutect2, varscan2
- SGTB | c.140del p.P47Qfs*6 | Frame Shift Del (DEL) | VAF 19/160 reads (12%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2242G>T p.V748L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by mutect2, varscan2
- TRBV19 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 36/210 reads (17%) | called by muse, mutect2, varscan2
- ANXA1 | c.570G>A p.E190= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV57413006; called by muse, mutect2, varscan2
- AP2B1 | c.435G>T p.V145= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as COSV52004114; called by muse, mutect2, varscan2
- CDH13 | c.729G>C p.P243= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV51862080, COSV51874880, COSV51878630; called by muse, mutect2, varscan2
- CLEC3A | c.342C>A p.P114= (on ENST00000651443; = p.P105= on NM_005752.6) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV55224119; called by muse, mutect2
- CNTN1 | c.1473G>T p.G491= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100751003; called by muse, mutect2
- COL15A1 | c.210G>A p.G70= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV66649993; called by muse, mutect2, varscan2
- COL9A1 | c.1596G>T p.G532= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV57894760; called by muse, mutect2, varscan2
- CSMD3 | c.2850A>G p.E950= (on ENST00000297405 / NM_001363185.1; = p.E846= on NM_052900.3) | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV52339803; called by muse, mutect2
- CYP4X1 | c.132C>A p.R44= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs757338909, COSV64152041; called by muse, mutect2
- DAPK1 | c.2580G>T p.L860= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV63792545; called by muse, varscan2
- DISC1 | c.2448G>A p.Q816= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV64103467, COSV64127008; called by muse, mutect2
- DNAH5 | c.402C>T p.D134= | Silent (SNP) | VAF 66/428 reads (15%) | catalogued as rs1436861240, COSV54256367; called by muse, mutect2, varscan2
- EFEMP2 | c.1140T>A p.A380= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as rs1256362720, COSV57261694; called by muse, mutect2, varscan2
- EIF1B | c.177T>A p.L59= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV51763027; called by muse, mutect2, varscan2
- FAM47C | c.204G>T p.T68= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100792322; called by muse, mutect2, varscan2
- FAM71B | c.1371G>T p.A457= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as COSV100261902, COSV57231747; called by muse, mutect2, varscan2
- FANCD2 | c.2181G>T p.P727= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV99810482; called by muse, mutect2
- FAT3 | c.8493C>G p.T2831= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV53182704; called by muse, mutect2, varscan2
- FBN2 | c.2706C>A p.I902= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99325318; called by muse, mutect2, varscan2
- FCER1A | c.531G>T p.T177= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs781630704, COSV100929283, COSV63668626; called by muse, mutect2, varscan2
- FSHR | c.720T>C p.N240= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV58636727; called by muse, mutect2
- GAL3ST2 | c.291C>A p.L97= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV51951930; called by muse, mutect2
- GPR4 | c.579G>T p.P193= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV59918681; called by muse, mutect2
- HAVCR1 | c.798G>T p.V266= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV59403900; called by muse, mutect2
- HS3ST5 | c.813G>A p.K271= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV57153355; called by muse, mutect2, varscan2
- IGKV1D-43 | c.18C>T p.P6= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs376915760; called by muse, mutect2, varscan2
- IGSF3 | c.2472G>T p.G824= (on ENST00000369486 / NM_001007237.3; = p.G844= on NM_001542.4) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV59599522; called by muse, mutect2, varscan2
- ITGB6 | c.2313T>C p.N771= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs1393603219, COSV51799273; called by muse, mutect2, varscan2
- KIAA1210 | c.1722T>G p.P574= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV68178104, COSV68180644; called by muse, mutect2, varscan2
- KIAA1210 | c.18G>T p.T6= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV68180330, COSV68180653; called by muse, mutect2
- KIAA2026 | c.5433G>T p.S1811= | Silent (SNP) | VAF 46/652 reads (7%) | catalogued as COSV67358155; called by muse, mutect2
- KRTAP6-2 | c.57A>T p.G19= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV58183156; called by muse, mutect2, varscan2
- LCE2C | c.42C>G p.P14= | Silent (SNP) | VAF 23/141 reads (16%) | catalogued as COSV100909393; called by muse, mutect2, varscan2
- LRRC4C | c.651G>C p.P217= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV53439640; called by muse, mutect2, varscan2
- LRRC58 | c.741G>A p.L247= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV55231392; called by muse, varscan2
- LRRN2 | c.609C>A p.A203= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV65784929; called by muse, mutect2, varscan2
- LYST | c.10416C>T p.Y3472= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs757982705, COSV67715105; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEC1 | c.2724G>T p.L908= | Silent (SNP) | VAF 36/422 reads (9%) | catalogued as COSV99594952; called by muse, mutect2
- METTL27 | c.664C>T p.L222= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV52895743, COSV52897449; called by muse, mutect2
- MPDZ | c.5352C>T p.T1784= | Silent (SNP) | VAF 13/161 reads (8%) | catalogued as rs766814033, COSV59925542; called by muse, mutect2
- MPDZ | c.4758G>A p.Q1586= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV59925563; called by muse, mutect2
- MSL3 | c.1308C>T p.D436= (on ENST00000312196 / NM_078629.4; = p.D270= on NM_006800.4) | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as COSV56491966; called by muse, mutect2
- MYH7 | c.1185G>C p.L395= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV62524804; called by muse, mutect2, varscan2
- NDST4 | c.624C>A p.P208= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV52140002; called by muse, mutect2, varscan2
- NEGR1 | c.240G>T p.A80= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs376667297, COSV60877466; called by muse, mutect2, varscan2
- NLRP3 | c.1293C>A p.A431= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV60232012; called by muse, mutect2, varscan2
- NOS2 | c.558C>T p.L186= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs139747007; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10AG1 | c.693C>T p.T231= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV56635208; called by muse, mutect2, varscan2
- OR2M4 | c.423T>C p.C141= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV60709926; called by muse, mutect2, varscan2
- OR51F1 | c.939C>T p.L313= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV58581076; called by muse, mutect2
- OR5V1 | c.30T>C p.T10= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV65830688; called by muse, mutect2, varscan2
- OR6K2 | c.267G>A p.R89= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs1306214461, COSV62743358, COSV62744356; called by muse, mutect2, varscan2
- OXCT1 | c.63G>A p.G21= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV52178037; called by muse, mutect2
- PCDHA4 | c.138C>A p.G46= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV63546763; called by muse, mutect2, varscan2
- PCDHGA8 | c.1707A>G p.T569= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV54048094; called by muse, mutect2
- PCNX2 | c.1212C>T p.T404= | Silent (SNP) | VAF 7/154 reads (5%) | catalogued as COSV50927152; called by muse, mutect2
- PKHD1 | c.10398G>A p.R3466= | Silent (SNP) | VAF 12/187 reads (6%) | catalogued as COSV64401901; called by muse, mutect2
- PLAT | c.243G>T p.V81= | Silent (SNP) | VAF 130/400 reads (33%) | catalogued as COSV54278573; called by muse, mutect2, varscan2
- PNLIPRP2 | c.369G>C p.V123= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100077632, COSV100077972; called by muse, mutect2
- PNLIPRP3 | c.612C>A p.V204= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV65049909; called by muse, mutect2, varscan2
- PREPL | c.831G>T p.V277= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV53219715; called by muse, mutect2
- PREX2 | c.630C>T p.N210= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV55793976, COSV55803000; called by muse, mutect2, varscan2
- PRR16 | c.339C>T p.I113= (on ENST00000407149 / NM_001300783.2; = p.I90= on NM_016644.2) | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs1393062179, COSV65400916, COSV65407205; called by muse, mutect2
- PTGFRN | c.1485A>G p.T495= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV67799757; called by muse, mutect2, varscan2
- RFC2 | c.21T>C p.C7= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV50017155; called by muse, mutect2
- ROR2 | c.2577C>T p.P859= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV65224080; called by muse, mutect2, varscan2
- RRP1 | c.921G>T p.L307= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV71856975; called by muse, mutect2, varscan2
- RYR3 | c.2046G>T p.V682= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as COSV66810502; called by muse, mutect2
- RYR3 | c.5856C>T p.C1952= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs755148509, COSV66810504; called by muse, mutect2
- SAR1A | c.456G>C p.G152= | Silent (SNP) | VAF 18/438 reads (4%) | catalogued as COSV100951550, COSV64698343; called by muse, mutect2
- SLC9A4 | c.2229G>T p.V743= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV54830132, COSV54840077; called by muse, mutect2, varscan2
- SPSB1 | c.252G>T p.T84= | Silent (SNP) | VAF 39/251 reads (16%) | catalogued as COSV60164836; called by muse, mutect2, varscan2
- SYT6 | c.294T>C p.S98= (on ENST00000610222 / NM_001366225.1; = p.S13= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/236 reads (6%) | catalogued as rs1349141716, COSV65776527; called by muse, mutect2
- TAF1C | c.2544C>A p.S848= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV58989760; called by muse, mutect2, varscan2
- TPTE | c.906C>A p.I302= (on ENST00000618007 / NM_199261.4; = p.I284= on NM_199259.4) | Silent (SNP) | VAF 20/368 reads (5%) | called by muse, mutect2
- TRAPPC8 | c.2916C>G p.P972= | Silent (SNP) | VAF 63/254 reads (25%) | catalogued as rs952279421, COSV51978271; called by muse, mutect2, varscan2
- TRIM49 | c.165C>T p.C55= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV61672155; called by muse, mutect2, varscan2
- TRPS1 | c.3693T>C p.A1231= (on ENST00000220888 / NM_001330599.2; = p.A1244= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as COSV55265338; called by muse, mutect2, varscan2
- TTC3 | c.3447A>T p.A1149= | Silent (SNP) | VAF 56/385 reads (15%) | catalogued as COSV61297063; called by muse, mutect2, varscan2
- UGGT1 | c.4251A>G p.L1417= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1439649164, COSV52142637; called by muse, mutect2, varscan2
- UGT2B17 | c.1194G>T p.A398= | Silent (SNP) | VAF 23/162 reads (14%) | catalogued as COSV100497172; called by muse, mutect2, varscan2
- UNC5C | c.2007G>T p.L669= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV71662651; called by muse, mutect2, varscan2
- VGLL3 | c.864C>T p.T288= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV101051927, COSV67354646; called by muse, mutect2, varscan2
- AC073310.1 | n.356C>T | RNA (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- CDKN2A | c.150+117T>A | Intron (SNP) | VAF 49/278 reads (18%) | called by muse, mutect2, varscan2
- KLK2 | c.630+28G>T | Intron (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100319856, COSV57570550; called by muse, mutect2, varscan2
- MASP1 | c.1303+5724C>A | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99961900; called by muse, mutect2, varscan2
- MBD1 | c.*33-218A>G | Intron (SNP) | VAF 31/100 reads (31%) | catalogued as COSV99495585; called by muse, mutect2, varscan2
- NBPF7 | n.491G>C | RNA (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- RPGR | c.2520+1470G>T | Intron (SNP) | VAF 39/294 reads (13%) | catalogued as COSV58840603; called by muse, mutect2, varscan2
- TTN | c.10360+3606T>C | Intron (SNP) | VAF 9/127 reads (7%) | catalogued as COSV60391508; called by muse, mutect2
- XIRP2 | c.*361G>A | 3'UTR (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99738992; called by muse, mutect2, varscan2
